TCGA case TCGA-XF-AAME — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: University of Southern California. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c8388ac0-975d-4f1e-8324-8cabdc75738d

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 64 years; Vital status: Dead; Days to death: 2,828 days (7.7 years).

Diagnoses (6)
1. Transitional cell carcinoma (the primary disease): ICD-O-3 morphology code: 8120/3; ICD-10 code: C67.9; Tissue or organ of origin: Bladder, NOS; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 64.2 years (23,448 days); Year of diagnosis: 2006; Method of diagnosis: Surgical Resection; AJCC staging edition: 6th; AJCC pathologic T: T2b; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Extracapsular extension present: No; Lymph nodes positive: 0; Lymph nodes tested: 76; Lymphatic invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 1,821 days (5.0 years); Days to treatment end: 1,871 days (5.1 years); Treatment dose: 45 Gy; Treatment outcome: Partial Response; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Gemcitabine; Days to treatment start: 2,500 days (6.8 years); Days to treatment end: 2,543 days (7.0 years); Treatment outcome: Partial Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Days to treatment start: 2,569 days (7.0 years); Days to treatment end: 2,569 days (7.0 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 2,569 days (7.0 years); Days to treatment end: 2,613 days (7.2 years); Treatment dose: 60 Gy; Treatment outcome: Partial Response; Treatment anatomic sites: Regional Site.
2. Recurrence of diagnosis 1 (Transitional cell carcinoma), site: Vagina, NOS. Age at diagnosis: 68.7 years (25,099 days); Days to diagnosis: 1,651 days (4.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 1,651 days (4.5 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.
3. Recurrence of diagnosis 1 (Transitional cell carcinoma), site: Vagina, NOS. Age at diagnosis: 69.1 years (25,229 days); Days to diagnosis: 1,781 days (4.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.
4. Recurrence of diagnosis 1 (Transitional cell carcinoma), site: Renal pelvis. Age at diagnosis: 70.8 years (25,868 days); Days to diagnosis: 2,420 days (6.6 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Surgery, NOS, for recurrent disease.
5. Metastasis of diagnosis 1 (Transitional cell carcinoma), site: Liver. Age at diagnosis: 71.5 years (26,111 days); Days to diagnosis: 2,663 days (7.3 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
6. Metastasis of diagnosis 1 (Transitional cell carcinoma), site: Lung, NOS. Age at diagnosis: 71.5 years (26,111 days); Days to diagnosis: 2,663 days (7.3 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (7 entries)
- Day 1,651 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Vagina, NOS; Days to recurrence: 1,651 days (4.5 years).
- Day 1,781 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Vagina, NOS; Days to recurrence: 1,781 days (4.9 years).
- Day 2,420 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Renal pelvis; Days to recurrence: 2,420 days (6.6 years).
- Day 2,663 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 2,663 days (7.3 years).
- Day 2,663 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 2,663 days (7.3 years).
- Days to follow up: 2,828 days (7.7 years); Disease response: With Tumor.
- Karnofsky performance status: 90.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 67 kg; Height: 160 cm; BMI: 26.2.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.
- Occupation type: Other.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-XF-AAME-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 250 mg.
  Slide TCGA-XF-AAME-01A-01-TSA: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 35; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-XF-AAME-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-XF-AAME-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Occupation current: home maker; Occupation primary: home maker; Occupation primary industry: home maker; Tobacco smoking history indicator: 1; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Non-Papillary; Anatomic organ subdivision: Bladder - NOS; Method initial path diagnosis: Transurethral resection (TURBT); Lymph nodes examined: Yes; Lymphovascular invasion: No; Incidental prostate cancer indicator: No.
- History non muscle invasive blca: Noninvasive bladder history: No.
- Drug treatment 1: Treatment best response: Clinical Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 2,828 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 2,828 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,651 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-XF-AAME-01A-12D-A42D-01): tumor purity 0.14, ploidy 2.29, whole-genome doublings 0.
